TCGA case TCGA-43-6647 — Lung Squamous Cell Carcinoma (TCGA-LUSC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Squamous Cell Neoplasms; Primary site: Bronchus and lung; Tissue source site: Christiana Healthcare. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/40e928e8-bedd-4b86-81bc-b581bfc897d4

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 69 years; Vital status: Alive.

Diagnoses (1)
1. Squamous cell carcinoma, NOS: ICD-O-3 morphology code: 8070/3; ICD-10 code: C34.3; Tissue or organ of origin: Lower lobe, lung; Site of resection or biopsy: Lung, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 69.5 years (25,378 days); Year of diagnosis: 2010; AJCC staging edition: 7th; AJCC pathologic T: T2b; AJCC pathologic N: N1; AJCC pathologic M: MX; AJCC pathologic stage: Stage IIB; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: RX; Days to last follow up: 757 days (2.1 years).
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin + Paclitaxel; Days to treatment start: 90 days; Days to treatment end: 153 days; Treatment outcome: Complete Response.
   Recorded as not given: adjuvant Radiation Therapy, NOS.

Follow-up (5 entries)
- Days to follow up: 183 days; Disease response: Tumor Free.
- Days to follow up: 379 days (1.0 years); Disease response: Tumor Free.
- Days to follow up: 757 days (2.1 years); Disease response: Tumor Free.
- ECOG performance status: 0; Timepoint: Preoperative.
- Karnofsky performance status: 100; Timepoint: Post Adjuvant Therapy.

Other clinical attributes
- FEV1 before bronchodilator (% of reference): 76.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for < or = 15 yrs; Pack years smoked: 36; Tobacco smoking onset year: 1959; Tobacco smoking quit year: 1995.

Biospecimens (4 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-43-6647-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 1; Intermediate dimension: 1; Shortest dimension: 0.5.
  Slide TCGA-43-6647-01A-01-BS1: Section location: Bottom; Percent tumor cells: 10; Percent tumor nuclei: 10; Percent normal cells: 90; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 50; Percent monocyte infiltration: 2; Percent neutrophil infiltration: 10.
  Slide TCGA-43-6647-01A-01-TS1: Section location: Top; Percent tumor cells: 90; Percent tumor nuclei: 65; Percent normal cells: 10; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 25; Percent monocyte infiltration: 2; Percent neutrophil infiltration: 5.
- Sample TCGA-43-6647-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-43-6647-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.
- Sample TCGA-43-6647-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Longest dimension: 2.5; Intermediate dimension: 1; Shortest dimension: 1.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Lung; Histologic diagnosis: Lung Squamous Cell Carcinoma- Not Otherwise Specified (NOS); History neoadjuvant treatment: No; Prospective collection: Yes; Retrospective collection: No; Tumor status: Tumor free; Tobacco smoking history indicator: 4; Anatomic organ subdivision: R-Lower; Pulmonary function test indicator: Yes.
- Drug treatment 1: Pharmaceutical therapy drug name: Taxol.
- Follow-up form 1: Treatment outcome first course: Complete Remission/Response; New tumor event diagnosis indicator: No; Tumor status: Tumor free; Treatment outcome at TCGA followup: Complete Remission/Response.
- Follow-up form 2: Lost to follow-up: No; Treatment outcome first course: Complete Remission/Response; New tumor event diagnosis indicator: No; Tumor status: Tumor free; Treatment outcome at TCGA followup: Complete Remission/Response; Performance status timing: Post-Adjuvant Therapy.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 757 days; disease-specific survival: no event (censored), 757 days; disease-free interval: no event (censored), 757 days; progression-free interval: no event (censored), 757 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-43-6647-01A-11D-1816-01): tumor purity 0.25, ploidy 1.81, whole-genome doublings 0.
